Somatic mutation profile of tumor specimen 0D9S48 from CCDI case PBBISC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.2 years (56 days).
Specimen 0D9S48: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ad39fd2-1fc6-4f28-b0c8-d1b782fe7027.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D9S2V (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32eaec86-ab98-4638-97b0-541d95ca8bd0

The open-access MAF lists 8 somatic variants for this specimen: 3 protein-altering or splice-affecting, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 4, Missense Mutation 2, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCB1 | c.157C>T p.R53* | Nonsense Mutation (SNP) | VAF 36/64 reads (56%) | catalogued as CM034687, COSV54096035, COSV54099986; called by muse, mutect2, varscan2
- MBD5 | c.802C>G p.L268V | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2
- SETX | c.7790T>A p.L2597Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.003); called by mutect2, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2, varscan2
- CALCOCO2 | c.825+77T>A | Intron (SNP) | VAF 5/32 reads (16%) | called by mutect2, varscan2
- REV3L | c.7419+59T>A | Intron (SNP) | VAF 4/18 reads (22%) | called by mutect2, varscan2
- SMIM8 | c.*22G>A | 3'UTR (SNP) | VAF 4/36 reads (11%) | called by muse, varscan2
- SON | c.6885+40G>A | Intron (SNP) | VAF 4/30 reads (13%) | called by muse, varscan2
